Somatic mutation profile of tumor specimen TARGET-15-SJMPAL012422-09A.3 (aliquot TARGET-15-SJMPAL012422-09A.3-01D) from TARGET case TARGET-15-SJMPAL012422, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.0 years (2,552 days).
Specimen TARGET-15-SJMPAL012422-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ececf74-d06b-4c8e-8084-aaa1e1281fa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL012422-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL012422-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ce5ec25-a431-4875-b223-ec7376148a2b

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, RNA 2, Intron 2, Silent 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMPD3 | c.374A>G p.Y125C (on ENST00000396553 / NM_001025389.2; = p.Y134C on NM_000480.3) | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as rs781521325; called by muse, mutect2, varscan2
- RPS6KA6 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.18); catalogued as COSV53125495; called by muse, mutect2, varscan2
- ARHGAP42 | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARMC9 | c.1117C>A p.Q373K | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2
- DIS3L2 | c.820_821insAGGCC p.R274Qfs*66 | Frame Shift Ins (INS) | VAF 26/66 reads (39%) | called by mutect2, pindel, varscan2
- HYDIN | c.4490A>T p.D1497V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4B | c.302C>A p.A101E | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- LRP1 | c.9118C>A p.R3040S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- MDGA2 | c.610G>T p.V204L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MUC4 | c.14966G>T p.C4989F (on ENST00000463781 / NM_018406.7; = p.C753F on NM_004532.6) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); called by muse, mutect2
- NAP1L3 | c.932T>C p.I311T | Missense Mutation (SNP) | VAF 35/35 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NELFCD | c.1511C>A p.T504K (on ENST00000602795; = p.T486K on NM_198976.4) | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2
- FREM1 | c.2937G>A p.L979= | Silent (SNP) | VAF 13/31 reads (42%) | called by muse, mutect2
- TTC6 | c.966T>C p.A322= (on ENST00000267368; = p.A1688= on NM_001310135.3) | Silent (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- CD3D | c.*28G>A | 3'UTR (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- IRF3 | c.165+228G>A | Intron (SNP) | VAF 33/54 reads (61%) | catalogued as rs763860251; called by muse, mutect2, varscan2
- RPS20 | c.3+84G>T | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- SMPD4BP | n.2560G>C | RNA (SNP) | VAF 9/21 reads (43%) | called by mutect2, varscan2
- SMPD4BP | n.2562_2563del | RNA (DEL) | VAF 8/20 reads (40%) | called by mutect2, varscan2
